Somatic mutation profile of tumor specimen ALCH-AE2Q-TTR1-A (aliquot ALCH-AE2Q-TTR1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-AE2Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,015 days).
Specimen ALCH-AE2Q-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bce2b4b-6933-4cc0-ab7e-e4373c71d70a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE2Q-NB1-A (Blood Derived Normal), aliquot ALCH-AE2Q-NB1-A-1-0-D-A604-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90d996f4-3dee-4add-a6a8-6fa754fe4ab4

The open-access MAF lists 434 somatic variants for this specimen: 303 protein-altering or splice-affecting, 73 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 73, Intron 26, Nonsense Mutation 20, RNA 10, 5'UTR 8, 3'UTR 8, Frame Shift Del 7, Splice Site 6, 5'Flank 6, Splice Region 5, Frame Shift Ins 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH11 | c.3133C>T p.R1045* | Nonsense Mutation (SNP) | VAF 31/254 reads (12%) | catalogued as rs377691013; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SALL1 | c.1115C>A p.S372* | Nonsense Mutation (SNP) | VAF 77/224 reads (34%) | catalogued as rs104894535, CM981786, CM991124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.923G>A p.W308* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | hotspot (GDC flag); catalogued as rs864622488, CM1313844, CM991159, COSV58822407; ClinVar: pathogenic; called by muse, varscan2
- ABCA13 | c.1293G>C p.L431F | Missense Mutation (SNP) | VAF 83/257 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs1409077668, COSV70033566; called by muse, mutect2, varscan2
- ACAN | c.6482C>A p.A2161E | Missense Mutation (SNP) | VAF 149/432 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as COSV61356917; called by muse, mutect2, varscan2
- ADAMTS16 | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as rs750965156; called by muse, mutect2, varscan2
- ADAMTS8 | c.2037C>A p.C679* | Nonsense Mutation (SNP) | VAF 48/286 reads (17%) | catalogued as COSV57290891; called by muse, mutect2, varscan2
- ADAMTS8 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs775536904, COSV57291111; called by muse, mutect2, varscan2
- ADGRG4 | c.3791C>A p.S1264Y | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV99796267; called by muse, mutect2, varscan2
- ANKRD11 | c.2539G>T p.D847Y | Missense Mutation (SNP) | VAF 197/401 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56356955; called by muse, mutect2, varscan2
- ARID1A | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV61387263, COSV61391621; called by muse, mutect2
- ASPH | c.252A>G p.L84= | Splice Region (SNP) | VAF 38/178 reads (21%) | catalogued as rs1343073193; called by muse, mutect2, varscan2
- ATF7IP | c.2510C>G p.S837C | Missense Mutation (SNP) | VAF 102/1004 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as COSV53770483; called by muse, mutect2
- B3GAT1 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56995030; called by muse, mutect2, varscan2
- BRCA2 | c.8382C>G p.F2794L | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs80359084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRPF1 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs1434715999; called by muse, mutect2, varscan2
- BSN | c.3940C>T p.P1314S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56530133; called by muse, mutect2, varscan2
- BTBD8 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61546205; called by muse, mutect2, varscan2
- C1orf54 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as rs782516643, COSV51743235; called by muse, mutect2, varscan2
- C2CD5 | c.1489A>G p.T497A | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.069); catalogued as rs767569115; called by muse, mutect2, varscan2
- CALCRL | c.1077G>C p.K359N | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV101130917, COSV101131009; called by muse, mutect2, varscan2
- CARD11 | c.864+1G>T p.X288_splice | Splice Site (SNP) | VAF 12/64 reads (19%) | catalogued as COSV67800435; called by muse, varscan2
- CCDC62 | c.977+1G>C p.X326_splice | Splice Site (SNP) | VAF 114/228 reads (50%) | catalogued as rs771967288, COSV53434837; called by muse, mutect2, varscan2
- CDH8 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV54853045; called by muse, mutect2
- CDKN2A | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 165/364 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11552823, CM080133, COSV58683884, COSV58697231, COSV58717232; called by muse, mutect2, varscan2
- CHRM2 | c.997A>G p.K333E | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV100280623; called by muse, mutect2, varscan2
- CNTN2 | c.2564G>A p.G855E | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.542); catalogued as rs1211430748, COSV100085367, COSV59353767; called by muse, mutect2, varscan2
- COL22A1 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV57355936; called by muse, mutect2, varscan2
- COL6A1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as rs1461577118; called by muse, mutect2, varscan2
- COQ5 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 124/383 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387361735, COSV99942186; called by muse, mutect2, varscan2
- CSMD1 | c.1175G>C p.R392T (on ENST00000520002; = p.R391T on NM_033225.6) | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV68200346; called by muse, mutect2, varscan2
- DDRGK1 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV63226995; called by muse, mutect2, varscan2
- DEAF1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs1389969543; called by muse, mutect2, varscan2
- DHX9 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 53/443 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.908); catalogued as rs1341615996; called by muse, mutect2, varscan2
- DLC1 | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV52321300, COSV99365068; called by muse, mutect2, varscan2
- DNMT3A | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs951361433, CM144155; called by muse, mutect2, varscan2
- DNPEP | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.105); catalogued as rs1374325564; called by muse, mutect2, varscan2
- DSEL | c.2843A>G p.H948R | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1453543314; called by muse, mutect2, varscan2
- DZIP3 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 73/430 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.037); catalogued as COSV64313719; called by muse, mutect2, varscan2
- EPGN | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs779175703; called by muse, mutect2, varscan2
- F13B | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 53/473 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs745383566; called by muse, mutect2, varscan2
- FAM110B | c.137A>G p.K46R | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.151); catalogued as rs747760336; called by muse, mutect2, varscan2
- FAM131B | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV58374530; called by muse, mutect2, varscan2
- FAP | c.467C>G p.S156W | Missense Mutation (SNP) | VAF 108/380 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51859814; called by muse, mutect2, varscan2
- FAT3 | c.3277A>G p.I1093V | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs749518639; called by muse, mutect2, varscan2
- FAT3 | c.7156G>A p.D2386N | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528105780; called by muse, mutect2, varscan2
- FHDC1 | c.823A>G p.I275V | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV99471813; called by muse, mutect2, varscan2
- FLG | c.7201C>A p.R2401S | Missense Mutation (SNP) | VAF 111/476 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs553468192, COSV64243028; called by muse, mutect2, varscan2
- FLG | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 326/1070 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100910658, COSV64249847; called by muse, mutect2, varscan2
- GALNT17 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs762495552, COSV61190791; called by muse, mutect2, varscan2
- GFAP | c.1128-3C>T | Splice Region (SNP) | VAF 39/103 reads (38%) | catalogued as rs1176683819; called by muse, mutect2, varscan2
- GIMAP1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as rs1373463897, COSV100212241; called by muse, mutect2, varscan2
- GOLGA6B | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 84/504 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as rs774132427; called by muse, mutect2, varscan2
- GPA33 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs373880766; called by muse, mutect2, varscan2
- GRIK4 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV70807124; called by muse, mutect2, varscan2
- HECW2 | c.2764G>A p.V922M | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as rs144884935; called by muse, mutect2, varscan2
- HMGXB4 | c.634C>G p.Q212E | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV53335448; called by muse, mutect2, varscan2
- HNRNPA1 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 61/468 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV52937419, COSV52938449; called by muse, mutect2, varscan2
- HYLS1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as COSV54988768; called by muse, mutect2, varscan2
- IFI44 | c.501G>T p.R167S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as rs765378040; called by muse, varscan2
- IFNB1 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 81/248 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.633); catalogued as rs1021655360; called by muse, mutect2, varscan2
- ILDR2 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 117/371 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV54829134; called by muse, mutect2, varscan2
- KCNC2 | c.402C>A p.F134L | Missense Mutation (SNP) | VAF 238/498 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54382525; called by muse, mutect2, varscan2
- KIR3DL1 | c.1318G>C p.V440L | Missense Mutation (SNP) | VAF 68/374 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV58491991; called by muse, mutect2, varscan2
- KRT17 | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs1309344989; called by muse, mutect2, varscan2
- LAIR1 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV100479840; called by muse, mutect2, varscan2
- LRP6 | c.1546G>T p.V516F | Missense Mutation (SNP) | VAF 71/440 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs1021205902; called by muse, mutect2, varscan2
- MAPK6 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1318026281; called by muse, mutect2
- MAPKBP1 | c.4399G>A p.E1467K (on ENST00000456763 / NM_001128608.2; = p.E1461K on NM_014994.3) | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs781103655; called by muse, mutect2, varscan2
- MRPL9 | c.486G>A p.A162= | Splice Region (SNP) | VAF 133/437 reads (30%) | catalogued as rs762267979, COSV58617756; called by muse, mutect2, varscan2
- NKG7 | c.260del p.P87Qfs*63 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs765087839; called by pindel, varscan2
- NLGN2 | c.2032G>T p.V678F | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57209659; called by muse, mutect2, varscan2
- NLRC5 | c.3208G>C p.E1070Q | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99346648; called by muse, mutect2, varscan2
- NTRK3 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 56/357 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV58149545; called by muse, mutect2, varscan2
- NXPE3 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 86/393 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs745327151; called by muse, mutect2, varscan2
- OR6P1 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1232919836, COSV58108516; called by muse, mutect2, varscan2
- OSBPL1A | c.2504G>A p.R835Q (on ENST00000319481 / NM_080597.4; = p.R322Q on NM_018030.4) | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.532); catalogued as rs754651669, COSV60205997; called by muse, mutect2, varscan2
- PAK1IP1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV52584469, COSV99468416, COSV99468494; called by muse, mutect2, varscan2
- PARD6B | c.790A>T p.S264C | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1326333229; called by muse, mutect2, varscan2
- PCDHB13 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 119/344 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as rs1554288152; called by muse, mutect2
- PCDHGA1 | c.1575C>A p.F525L | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.044); catalogued as COSV100966162; called by muse, mutect2, varscan2
- PDZRN4 | c.3062C>G p.P1021R (on ENST00000402685 / NM_001164595.2; = p.P763R on NM_013377.4) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54216958; called by muse, mutect2
- PEX5L | c.1478C>A p.A493E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99829769; called by muse, mutect2, varscan2
- PLXNA2 | c.4438G>A p.E1480K | Missense Mutation (SNP) | VAF 99/392 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1269275813, COSV65437873; called by muse, mutect2, varscan2
- PMS2 | c.2446G>T p.V816L | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs876659479; ClinVar: uncertain significance; called by muse, varscan2
- PRG4 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 80/606 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV100798256; called by muse, varscan2
- QSER1 | c.283C>T p.H95Y (on ENST00000399302; = p.H224Y on NM_001076786.3) | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV67899604; called by muse, mutect2, varscan2
- RAB40B | c.677C>G p.S226W | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1464517236, COSV53915617; called by muse, mutect2, varscan2
- RAP2C | c.544G>T p.V182F | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV61683689; called by mutect2, varscan2
- RIF1 | c.2257G>A p.V753M | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.246); catalogued as rs766829689; called by muse, mutect2, varscan2
- RIT1 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 105/346 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs948974325; called by muse, mutect2, varscan2
- RNF213 | c.14935C>G p.L4979V | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV60407587; called by muse, mutect2, varscan2
- RYR2 | c.8590G>T p.G2864* | Nonsense Mutation (SNP) | VAF 20/142 reads (14%) | catalogued as COSV100767266, COSV63701361; called by muse, mutect2, varscan2
- SFSWAP | c.2038C>G p.Q680E | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55525912; called by muse, mutect2, varscan2
- SLC12A7 | c.513G>C p.M171I | Missense Mutation (SNP) | VAF 53/367 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1365555968; called by muse, mutect2, varscan2
- SLC16A9 | c.1311C>G p.F437L | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.78); catalogued as rs757332576; called by muse, mutect2, varscan2
- SLC1A2 | c.1309G>T p.V437F | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs374090482; called by muse, mutect2, varscan2
- SLC46A1 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs782811181; called by muse, mutect2, varscan2
- SLFN13 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 59/324 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs749611953; called by muse, mutect2, varscan2
- SOWAHB | c.1187A>T p.D396V | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV57555646; called by muse, mutect2, varscan2
- STIM2 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); catalogued as rs756946958; called by muse, mutect2, varscan2
- STK11 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 86/190 reads (45%) | catalogued as CM055546, COSV100480591, COSV58827688; called by muse, varscan2
- TCEA3 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV101508323; called by muse, mutect2, varscan2
- TESK2 | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1258308656; called by muse, mutect2, varscan2
- TMEM200A | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1259176010; called by muse, mutect2, varscan2
- TMEM241 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV101271667, COSV67245885; called by muse, mutect2, varscan2
- USH2A | c.12541C>A p.P4181T | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as COSV56361264; called by mutect2, varscan2
- VWF | c.5822G>T p.G1941V | Missense Mutation (SNP) | VAF 245/437 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1180283088; called by muse, mutect2, varscan2
- WBP2 | c.401C>G p.S134C | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1056277129; called by muse, mutect2, varscan2
- WNK4 | c.3154G>C p.E1052Q | Missense Mutation (SNP) | VAF 77/431 reads (18%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.767); catalogued as COSV99891216; called by muse, mutect2, varscan2
- XDH | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 157/611 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as rs761942456; called by muse, mutect2, varscan2
- ZEB2 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 26/145 reads (18%) | catalogued as CM078054, COSV57966196; called by muse, mutect2, varscan2
- ZFYVE19 | c.799G>A p.D267N (on ENST00000355341 / NM_001077268.2; = p.D257N on NM_032850.5) | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.536); catalogued as rs1351648333; called by muse, mutect2, varscan2
- ZHX1 | c.2363A>G p.Y788C | Missense Mutation (SNP) | VAF 151/319 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1563808385; called by muse, mutect2, varscan2
- ZNF208 | c.1105T>A p.Y369N | Missense Mutation (SNP) | VAF 114/309 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs370096318; called by muse, mutect2, varscan2
- ZNF254 | c.1508C>G p.S503* | Nonsense Mutation (SNP) | VAF 103/502 reads (21%) | catalogued as rs753170366, COSV100741694; called by muse, mutect2, varscan2
- ZNF423 | c.3179C>T p.A1060V (on ENST00000563137 / NM_001379286.1; = p.A1052V on NM_015069.4) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.047); catalogued as rs757185741, COSV52187884; called by muse, varscan2
- ZNF469 | c.3236G>A p.R1079Q (on ENST00000437464; = p.R1107Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.043); catalogued as rs281865148; ClinVar: benign; called by muse, mutect2, varscan2
- ZNF571 | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs373799629; called by muse, varscan2
- ZNF808 | c.1357A>G p.K453E | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1419309854; called by muse, mutect2, varscan2
- ZSWIM2 | c.243-1G>T p.X81_splice | Splice Site (SNP) | VAF 73/269 reads (27%) | catalogued as COSV54574528, COSV54577057, COSV54579018; called by muse, mutect2, varscan2
- ABCA3 | c.1310T>A p.L437H | Missense Mutation (SNP) | VAF 191/417 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ABHD13 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 154/478 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AC139530.2 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.073); called by muse, varscan2
- ADGRB3 | c.2795_2796insC p.Q932Hfs*6 | Frame Shift Ins (INS) | VAF 23/144 reads (16%) | called by mutect2, pindel*, varscan2
- AKAP8L | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 55/286 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AKAP9 | c.9778G>C p.E3260Q (on ENST00000359028; = p.E3236Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/443 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALDH18A1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 100/286 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AOC1 | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); called by muse, mutect2
- APC | c.2468C>G p.S823* | Nonsense Mutation (SNP) | VAF 107/300 reads (36%) | called by muse, mutect2, varscan2
- APOB | c.12047A>G p.D4016G | Missense Mutation (SNP) | VAF 63/450 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ASAP3 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- ATF7IP | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 45/352 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- AVPR2 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCORL1 | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEND2 | c.1776dup p.R593Tfs*12 | Frame Shift Ins (INS) | VAF 22/160 reads (14%) | called by mutect2, pindel
- BEST4 | c.1285A>T p.N429Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- BOD1L1 | c.8231A>G p.D2744G | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRIP1 | c.1936-1G>T p.X646_splice | Splice Site (SNP) | VAF 54/357 reads (15%) | called by muse, mutect2, varscan2
- C10orf90 | c.1917A>C p.K639N | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNG5 | c.326T>A p.F109Y | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- CC2D1B | c.1960G>C p.E654Q | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC33 | c.2209T>A p.S737T | Missense Mutation (SNP) | VAF 41/303 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC39 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 63/497 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CD1B | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 95/328 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH7 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CENPW | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 191/446 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CERT1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CFAP221 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CFAP61 | c.326T>A p.V109E | Missense Mutation (SNP) | VAF 101/317 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHGA | c.1016C>G p.S339C | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, varscan2
- CHN1 | c.225C>A p.S75R | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CIT | c.4636C>T p.P1546S | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CKB | c.291_292delinsA p.H97Qfs*31 | Frame Shift Del (DEL) | VAF 53/350 reads (15%) | called by pindel, varscan2*
- COL23A1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CPB2 | c.888G>C p.L296F | Missense Mutation (SNP) | VAF 69/342 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DENND1B | c.441G>T p.L147F | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- DFFB | c.992A>G p.K331R | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHX37 | c.1921G>T p.V641F | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- DNAH11 | c.158T>C p.F53S | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- DNAJC15 | c.280A>T p.R94W | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- DQX1 | c.1789T>C p.S597P | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DRD5 | c.411C>A p.D137E | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EIF3D | c.1634-1G>C p.X545_splice | Splice Site (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- EIF3M | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELMO2 | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- EML4 | c.1972T>G p.F658V | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ENOX1 | c.1596C>G p.S532R | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERCC6L2 | c.4450G>A p.E1484K | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- EXT1 | c.1115T>C p.I372T | Missense Mutation (SNP) | VAF 103/429 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM171A1 | c.161T>A p.I54N | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FAM53C | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- FANCI | c.2992C>A p.P998T (on ENST00000310775 / NM_001376911.1; = p.P938T on NM_018193.3) | Missense Mutation (SNP) | VAF 83/603 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- FGF23 | c.77C>G p.P26R | Missense Mutation (SNP) | VAF 62/427 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FLNC | c.2876A>G p.N959S | Missense Mutation (SNP) | VAF 67/442 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLRT2 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- FRMD5 | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- FXR1 | c.882A>T p.G294= | Splice Region (SNP) | VAF 19/159 reads (12%) | called by muse, mutect2, varscan2
- GIMAP2 | c.140C>G p.A47G | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- GK2 | c.558G>C p.L186F | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- GOLGA8H | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 40/701 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); called by muse, mutect2
- GORAB | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPRC5C | c.297G>C p.E99D (on ENST00000652232; = p.E54D on NM_018653.4) | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- GRK3 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEPHL1 | c.2884G>C p.E962Q | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HERC2 | c.10774_10775del p.V3592Hfs*25 | Frame Shift Del (DEL) | VAF 77/253 reads (30%) | called by pindel, varscan2
- HMGXB4 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 83/285 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, varscan2
- HMGXB4 | c.370T>C p.S124P | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- HMGXB4 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- HMGXB4 | c.1089_1091del p.P364del | In Frame Del (DEL) | VAF 102/386 reads (26%) | called by pindel, varscan2
- IL16 | c.2194A>T p.N732Y (on ENST00000302987 / NM_172217.5; = p.N31Y on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- IMPG1 | c.1955C>A p.A652D | Missense Mutation (SNP) | VAF 98/314 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INA | c.1228A>T p.S410C | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.775); called by muse, varscan2
- INSR | c.3590T>C p.L1197P | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- IQGAP3 | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ITGA11 | c.3525G>C p.R1175S | Missense Mutation (SNP) | VAF 145/464 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KCNA6 | c.661del p.S221Vfs*76 | Frame Shift Del (DEL) | VAF 22/135 reads (16%) | called by mutect2, pindel, varscan2
- KCNC3 | c.1045A>G p.T349A | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- KCNK18 | c.517A>C p.T173P | Missense Mutation (SNP) | VAF 119/265 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNK18 | c.668G>A p.C223Y | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- KCTD8 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA0100 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- KRTAP21-1 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LAIR1 | c.657G>T p.R219S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LCT | c.3815C>A p.T1272N | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LHX8 | c.347A>T p.Y116F | Missense Mutation (SNP) | VAF 54/396 reads (14%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.989); called by muse, mutect2
- LIPN | c.518C>A p.S173* | Nonsense Mutation (SNP) | VAF 189/383 reads (49%) | called by muse, mutect2, varscan2
- LMBRD2 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 63/519 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- LOXL1 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- LRP1 | c.3404C>G p.S1135W | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.9398G>C p.R3133T | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP5 | c.3260A>G p.Q1087R | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- LRRC37B | c.1906T>A p.C636S | Missense Mutation (SNP) | VAF 123/366 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- LRRTM1 | c.904T>A p.S302T | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- LTBP2 | c.1251G>T p.W417C | Missense Mutation (SNP) | VAF 67/316 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LTBP2 | c.1250G>T p.W417L | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAGI2 | c.3294C>A p.Y1098* | Nonsense Mutation (SNP) | VAF 24/103 reads (23%) | called by muse, mutect2, varscan2
- MAP2K1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 86/409 reads (21%) | called by muse, mutect2, varscan2
- MBD5 | c.197G>C p.C66S | Missense Mutation (SNP) | VAF 71/434 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MCOLN3 | c.823T>A p.S275T | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MED24 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 47/285 reads (16%) | called by muse, mutect2, varscan2
- MICU1 | c.1226C>G p.S409* (on ENST00000361114 / NM_001195518.2; = p.S415* on NM_006077.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 107/316 reads (34%) | called by muse, mutect2, varscan2
- MXRA7 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 11/101 reads (11%) | PolyPhen benign (0.202); called by muse, mutect2, varscan2
- MYO9A | c.4234T>G p.F1412V | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NBAS | c.1072C>G p.Q358E | Missense Mutation (SNP) | VAF 166/631 reads (26%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- NCOR2 | c.7102C>G p.L2368V | Missense Mutation (SNP) | VAF 58/321 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- NDUFAF3 | c.104C>G p.S35W | Missense Mutation (SNP) | VAF 89/185 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- NPHP4 | c.2755A>G p.M919V | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- NSMF | c.654C>A p.F218L | Missense Mutation (SNP) | VAF 84/405 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NUP54 | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- NYNRIN | c.2619G>C p.K873N | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OGA | c.1826C>G p.S609* | Nonsense Mutation (SNP) | VAF 80/197 reads (41%) | called by muse, varscan2
- OR11A1 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2J2 | c.653C>A p.T218N | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR4C16 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OR5W2 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PBX1 | c.1186C>G p.P396A | Missense Mutation (SNP) | VAF 106/413 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- PCDHA6 | c.2325C>G p.S775R | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- PCNT | c.2211G>C p.K737N | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- PDE2A | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PDGFRB | c.2330A>C p.N777T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.046); called by muse, mutect2
- PITX3 | c.417dup p.L140Afs*122 | Frame Shift Ins (INS) | VAF 12/76 reads (16%) | called by mutect2, pindel
- PLEKHA8 | c.575T>A p.L192Q | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- PPP1R9A | c.2896G>A p.D966N | Missense Mutation (SNP) | VAF 63/488 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PRAMEF17 | c.311A>T p.D104V | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PRMT5 | c.491G>A p.R164K | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PRSS8 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PSME3 | c.360G>C p.E120D | Missense Mutation (SNP) | VAF 74/476 reads (16%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PTDSS2 | c.821A>T p.K274M | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- PTEN | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 43/272 reads (16%) | called by muse, mutect2, varscan2
- PTPRU | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PTPRU | c.2506+1dup | Frame Shift Ins (INS) | VAF 24/96 reads (25%) | called by mutect2, pindel, varscan2
- RBM19 | c.2153A>C p.E718A | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- RFXAP | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 45/304 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RRNAD1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 65/451 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RTL3 | c.506A>T p.E169V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.397); called by mutect2, varscan2
- RUNX3 | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN3A | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 79/525 reads (15%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SH3D21 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SHFL | c.572G>T p.W191L | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIGLEC1 | c.1943del p.P648Hfs*16 | Frame Shift Del (DEL) | VAF 13/94 reads (14%) | called by mutect2, pindel, varscan2
- SIGLEC5 | c.924A>C p.E308D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.047); called by muse, mutect2
- SLC10A6 | c.189G>T p.R63S | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- SLC35G3 | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by mutect2, varscan2
- SNX19 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- SPDYC | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.883); called by mutect2, varscan2
- SPEG | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, varscan2
- SPON2 | c.850T>G p.S284A | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, varscan2
- SPTA1 | c.1964C>G p.S655C | Missense Mutation (SNP) | VAF 171/652 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SRGAP3 | c.761T>G p.I254R | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- ST8SIA3 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 188/445 reads (42%) | PolyPhen benign (0.021); called by muse, mutect2, varscan2
- STAB2 | c.5178_5179del p.N1728Ffs*29 | Frame Shift Del (DEL) | VAF 28/258 reads (11%) | called by mutect2, pindel, varscan2
- TAF1L | c.5131C>A p.L1711M | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- TATDN2 | c.1513C>G p.L505V | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- TBC1D14 | c.1592C>G p.S531C | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TBC1D5 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 63/426 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- TIGD1 | c.1041G>C p.L347F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TM4SF4 | c.113A>T p.D38V | Missense Mutation (SNP) | VAF 53/412 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- TMEM132C | c.2520_2544del p.Y841Rfs*21 | Frame Shift Del (DEL) | VAF 28/199 reads (14%) | called by mutect2, pindel
- TMEM225B | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 55/354 reads (16%) | called by muse, mutect2, varscan2
- TNKS2 | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 35/180 reads (19%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.3807G>T p.M1269I | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TP53 | c.81_96+2del p.X27_splice | Splice Site (DEL) | VAF 54/190 reads (28%) | called by mutect2, pindel, varscan2
- TRIM51GP | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIO | c.7741C>G p.L2581V | Missense Mutation (SNP) | VAF 81/541 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TRIP11 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPC6 | c.2006C>T p.T669I | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSHZ3 | c.2294C>A p.T765N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, varscan2
- TTN | c.85204A>C p.T28402P (on ENST00000591111; = p.T20978P on NM_003319.4) | Missense Mutation (SNP) | VAF 38/196 reads (19%) | PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- TTN | c.27963C>A p.F9321L (on ENST00000591111; = p.F8394L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/425 reads (17%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.4646-7C>G | Splice Region (SNP) | VAF 88/636 reads (14%) | called by muse, mutect2, varscan2
- TWIST2 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- UFD1 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UQCC1 | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USH2A | c.7714G>A p.G2572S | Missense Mutation (SNP) | VAF 49/321 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UTP15 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- WDFY4 | c.2591T>G p.I864S | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- YAP1 | c.942G>C p.E314D (on ENST00000282441 / NM_001130145.3; = p.E276D on NM_006106.5) | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF227 | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ZNF431 | c.1168C>A p.H390N | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF605 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2
- ZNF831 | c.4874A>T p.D1625V | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.243); called by muse, varscan2
- ZNF831 | c.4928C>G p.S1643C | Missense Mutation (SNP) | VAF 78/306 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.042); called by muse, varscan2
- ABCF2 | c.342T>C p.Y114= | Silent (SNP) | VAF 130/491 reads (26%) | catalogued as rs1408504164; called by muse, mutect2, varscan2
- ADAMTS12 | c.2937C>T p.C979= | Silent (SNP) | VAF 80/565 reads (14%) | catalogued as rs944632546, COSV61265817; called by muse, mutect2, varscan2
- AMER3 | c.1863T>A p.T621= | Silent (SNP) | VAF 29/169 reads (17%) | called by muse, mutect2, varscan2
- ANXA6 | c.861C>T p.L287= | Silent (SNP) | VAF 26/207 reads (13%) | catalogued as rs769951302; called by muse, mutect2, varscan2
- AOC1 | c.849C>A p.S283= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2
- ARAP1 | c.2685C>T p.F895= (on ENST00000393609 / NM_001040118.2; = p.F650= on NM_015242.4) | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV100502095; called by muse, mutect2, varscan2
- BDP1 | c.1740G>A p.V580= | Silent (SNP) | VAF 49/329 reads (15%) | called by muse, mutect2, varscan2
- CAMTA1 | c.2880C>A p.L960= | Silent (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- CFAP99 | c.825C>T p.F275= | Silent (SNP) | VAF 51/290 reads (18%) | called by muse, mutect2, varscan2
- CHAF1A | c.1125G>A p.K375= | Silent (SNP) | VAF 63/267 reads (24%) | called by muse, mutect2, varscan2
- CHSY3 | c.696C>T p.S232= | Silent (SNP) | VAF 74/204 reads (36%) | catalogued as rs774477266; called by muse, mutect2, varscan2
- CKAP4 | c.1389A>G p.A463= | Silent (SNP) | VAF 33/290 reads (11%) | called by muse, mutect2, varscan2
- COL15A1 | c.312T>G p.G104= | Silent (SNP) | VAF 24/127 reads (19%) | called by muse, mutect2, varscan2
- CR1L | c.1698C>T p.F566= | Silent (SNP) | VAF 46/211 reads (22%) | called by muse, varscan2
- CRNN | c.1191G>A p.E397= | Silent (SNP) | VAF 124/527 reads (24%) | catalogued as rs1263846246; called by muse, mutect2, varscan2
- CSMD2 | c.9426G>A p.Q3142= | Silent (SNP) | VAF 36/332 reads (11%) | catalogued as COSV53876515; called by muse, mutect2, varscan2
- DDX55 | c.597C>G p.G199= | Silent (SNP) | VAF 36/181 reads (20%) | catalogued as COSV53017260; called by muse, mutect2, varscan2
- DDX60 | c.4077A>G p.R1359= | Silent (SNP) | VAF 19/508 reads (4%) | called by muse, mutect2
- ELAC2 | c.1722C>T p.H574= | Silent (SNP) | VAF 92/432 reads (21%) | catalogued as rs770617287, COSV61649101; ClinVar: likely benign; called by muse, mutect2, varscan2
- ETS1 | c.543C>T p.I181= | Silent (SNP) | VAF 60/192 reads (31%) | called by muse, mutect2, varscan2
- EYS | c.927C>T p.C309= | Silent (SNP) | VAF 108/301 reads (36%) | called by muse, mutect2, varscan2
- FKTN | c.411C>T p.C137= | Silent (SNP) | VAF 78/355 reads (22%) | catalogued as rs537001725; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GNAS | c.402C>T p.F134= | Silent (SNP) | VAF 67/206 reads (33%) | catalogued as rs771418632, COSV100005720; called by muse, mutect2, varscan2
- GRM1 | c.588T>G p.T196= | Silent (SNP) | VAF 24/736 reads (3%) | catalogued as COSV51117494, COSV51140435; called by muse, mutect2
- HCN1 | c.1806G>C p.L602= | Silent (SNP) | VAF 107/385 reads (28%) | called by muse, mutect2, varscan2
- HOXD9 | c.297C>T p.Y99= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs1408564156; called by muse, mutect2
- IGKV4-1 | c.108C>G p.G36= | Silent (SNP) | VAF 26/171 reads (15%) | called by muse, mutect2
- ISCA2 | c.63G>A p.P21= | Silent (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- KLHL22 | c.474G>C p.L158= | Silent (SNP) | VAF 49/461 reads (11%) | called by muse, mutect2, varscan2
- LCLAT1 | c.726A>T p.V242= | Silent (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- LHX8 | c.345T>C p.C115= | Silent (SNP) | VAF 55/394 reads (14%) | called by muse, mutect2
- MAN2B2 | c.486A>G p.L162= | Silent (SNP) | VAF 34/170 reads (20%) | catalogued as rs755558768; called by muse, mutect2, varscan2
- MED13 | c.5730C>A p.L1910= | Silent (SNP) | VAF 41/305 reads (13%) | catalogued as COSV67267501; called by muse, mutect2, varscan2
- MS4A14 | c.465C>T p.F155= | Silent (SNP) | VAF 41/266 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.33603C>A p.S11201= | Silent (SNP) | VAF 53/130 reads (41%) | called by muse, mutect2, varscan2
- MZF1 | c.549G>A p.V183= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs764830623, COSV53043214; called by muse, mutect2, varscan2
- NDUFAF3 | c.15C>G p.L5= | Silent (SNP) | VAF 150/286 reads (52%) | called by muse, mutect2, varscan2
- NEK5 | c.924A>T p.G308= | Silent (SNP) | VAF 56/244 reads (23%) | called by muse, mutect2, varscan2
- OLFM3 | c.960G>T p.G320= (on ENST00000338858 / NM_001288821.1; = p.G300= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/186 reads (15%) | catalogued as COSV58798430; called by muse, mutect2, varscan2
- PAPPA2 | c.2559C>T p.I853= | Silent (SNP) | VAF 20/176 reads (11%) | catalogued as rs767298759, COSV100867181; called by muse, mutect2, varscan2
- PCDH17 | c.1407G>A p.P469= | Silent (SNP) | VAF 56/260 reads (22%) | catalogued as rs770777439, COSV64973740; called by muse, mutect2, varscan2
- PCDHB10 | c.156G>A p.L52= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as COSV99505063; called by muse, mutect2, varscan2
- PCNT | c.7053G>T p.L2351= | Silent (SNP) | VAF 34/118 reads (29%) | called by muse, mutect2, varscan2
- PDZRN4 | c.2541C>T p.A847= (on ENST00000402685 / NM_001164595.2; = p.A589= on NM_013377.4) | Silent (SNP) | VAF 65/297 reads (22%) | catalogued as rs1471964882, COSV100113875; called by muse, mutect2, varscan2
- PHF2 | c.1950C>G p.L650= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV63684288; called by muse, varscan2
- PITPNM3 | c.715C>A p.R239= | Silent (SNP) | VAF 109/283 reads (39%) | called by muse, mutect2, varscan2
- PKP3 | c.1578C>T p.N526= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs759140506; called by muse, mutect2, varscan2
- PRSS54 | c.81C>T p.S27= | Silent (SNP) | VAF 24/255 reads (9%) | called by muse, mutect2, varscan2
- PWWP3A | c.1446C>T p.F482= (on ENST00000627377; = p.F481= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 71/182 reads (39%) | called by muse, mutect2, varscan2
- RABEP2 | c.1284G>A p.A428= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs777877547, COSV100707205, COSV62870549; called by muse, mutect2, varscan2
- RAG1 | c.396T>A p.P132= | Silent (SNP) | VAF 63/295 reads (21%) | called by muse, mutect2, varscan2
- RIPOR2 | c.708G>A p.L236= | Silent (SNP) | VAF 81/272 reads (30%) | catalogued as rs1267990992; called by muse, mutect2, varscan2
- RNF213 | c.15387C>T p.F5129= | Silent (SNP) | VAF 140/477 reads (29%) | called by muse, varscan2
- RPGRIP1 | c.2967G>A p.G989= | Silent (SNP) | VAF 48/247 reads (19%) | called by muse, mutect2, varscan2
- RYR2 | c.1557G>C p.G519= | Silent (SNP) | VAF 26/173 reads (15%) | called by muse, mutect2, varscan2
- SALL1 | c.2499T>C p.P833= | Silent (SNP) | VAF 104/267 reads (39%) | called by muse, mutect2, varscan2
- SCAND1 | c.228C>G p.L76= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as rs540385747; called by muse, mutect2, varscan2
- SCGN | c.111C>T p.L37= | Silent (SNP) | VAF 25/189 reads (13%) | called by muse, mutect2, varscan2
- SDCCAG8 | c.1701G>C p.L567= | Silent (SNP) | VAF 55/318 reads (17%) | called by muse, mutect2, varscan2
- SLC5A6 | c.786G>A p.G262= | Silent (SNP) | VAF 47/327 reads (14%) | catalogued as rs765809428; called by muse, mutect2, varscan2
- SLC9C2 | c.609G>A p.R203= | Silent (SNP) | VAF 21/207 reads (10%) | catalogued as COSV100876527; called by muse, mutect2, varscan2
- SLFN13 | c.1422C>A p.T474= | Silent (SNP) | VAF 43/239 reads (18%) | called by muse, mutect2, varscan2
- SPHKAP | c.111G>A p.P37= | Silent (SNP) | VAF 132/340 reads (39%) | catalogued as rs201911651, COSV60878469; called by muse, mutect2, varscan2
- SUZ12 | c.2133A>T p.G711= | Silent (SNP) | VAF 39/107 reads (36%) | called by muse, mutect2, varscan2
- THRB | c.264G>A p.T88= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as rs768009297; called by muse, mutect2, varscan2
- TMEM132E | c.2298C>T p.G766= (on ENST00000321639; = p.G856= on NM_001304438.2) | Silent (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- TPR | c.1995T>C p.A665= | Silent (SNP) | VAF 99/667 reads (15%) | catalogued as COSV66600193; called by muse, mutect2, varscan2
- UMODL1 | c.306C>G p.L102= | Silent (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- VILL | c.261G>T p.L87= | Silent (SNP) | VAF 103/299 reads (34%) | catalogued as rs370182077; called by muse, mutect2, varscan2
- WDR93 | c.1338T>C p.P446= | Silent (SNP) | VAF 24/130 reads (18%) | called by muse, mutect2, varscan2
- ZBTB8OS | c.351C>T p.F117= | Silent (SNP) | VAF 66/200 reads (33%) | catalogued as COSV59385238; called by muse, mutect2, varscan2
- ZFHX4 | c.10731T>A p.S3577= | Silent (SNP) | VAF 57/287 reads (20%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.1110C>G p.T370= (on ENST00000252463; = p.T425= on NM_032805.3) | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as rs764799478; called by muse, mutect2, varscan2
- ABI3BP | c.1577-7710G>T | Intron (SNP) | VAF 52/287 reads (18%) | called by muse, mutect2, varscan2
- AC020637.1 | n.801-444G>T | Intron (SNP) | VAF 46/226 reads (20%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-10062A>G | Intron (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- ACYP2 | c.-71C>G | 5'UTR (SNP) | VAF 80/204 reads (39%) | catalogued as rs767196072; called by muse, mutect2, varscan2
- ADAM21P1 | n.802C>T | RNA (SNP) | VAF 48/211 reads (23%) | catalogued as rs775556370; called by muse, mutect2, varscan2
- AKR1C1 | c.570+735G>C | Intron (SNP) | VAF 137/338 reads (41%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1356G>A | Intron (SNP) | VAF 36/271 reads (13%) | called by mutect2, varscan2
- AP000769.5 | chr11:65499292 del AAAACATGACGGAGGTTGAGATGAAGCTTCTTCATGGAGTA | 5'Flank (DEL) | VAF 22/274 reads (8%) | called by mutect2, pindel
- ARHGEF10L | c.2172-326C>T | Intron (SNP) | VAF 22/205 reads (11%) | called by muse, varscan2
- CEP41 | c.*2481dup | 3'UTR (INS) | VAF 33/302 reads (11%) | catalogued as rs1562972742; called by mutect2, pindel, varscan2
- DCHS2 | n.8576C>A | RNA (SNP) | VAF 34/165 reads (21%) | catalogued as COSV61775379; called by muse, mutect2, varscan2
- DNAJC19 | c.*633C>T | 3'UTR (SNP) | VAF 40/175 reads (23%) | called by muse, mutect2, varscan2
- DOCK10 | c.124-15272A>T | Intron (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- DTNA | c.*2659G>A | 3'UTR (SNP) | VAF 50/236 reads (21%) | called by muse, mutect2, varscan2
- EEF1G | c.-4C>T | 5'UTR (SNP) | VAF 59/286 reads (21%) | called by muse, mutect2, varscan2
- ERBB2 | c.1514-38C>T | Intron (SNP) | VAF 43/121 reads (36%) | catalogued as rs1261475108; called by muse, mutect2, varscan2
- ETV5 | c.-75+425G>C | Intron (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- FARP1 | c.*4904G>C | 3'UTR (SNP) | VAF 140/338 reads (41%) | catalogued as rs113209502; called by muse, mutect2, varscan2
- GABBR1 | c.*538C>T | 3'UTR (SNP) | VAF 12/131 reads (9%) | catalogued as rs1360802667; called by muse, mutect2, varscan2
- GASK1A | c.1413+59C>A | Intron (SNP) | VAF 65/386 reads (17%) | called by muse, mutect2, varscan2
- GRM8 | c.727+30350A>T | Intron (SNP) | VAF 40/178 reads (22%) | called by muse, mutect2, varscan2
- GSG1L | c.551-5516C>A | Intron (SNP) | VAF 63/197 reads (32%) | called by muse, mutect2, varscan2
- GVINP1 | n.3545G>A | RNA (SNP) | VAF 33/173 reads (19%) | catalogued as rs1488835213; called by muse, mutect2, varscan2
- HDAC8 | chrX:72572844 G>A | 5'Flank (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- HUS1 | c.465+384G>T | Intron (SNP) | VAF 51/313 reads (16%) | called by muse, mutect2, varscan2
- IFT172 | c.-18G>A | 5'UTR (SNP) | VAF 24/137 reads (18%) | called by muse, mutect2, varscan2
- KCNAB1 | c.275+22404C>G | Intron (SNP) | VAF 43/318 reads (14%) | catalogued as COSV101051355; called by muse, mutect2, varscan2
- KIAA2012 | c.369+1835C>A | Intron (SNP) | VAF 28/260 reads (11%) | called by muse, mutect2, varscan2
- LINC02817 | n.244T>G | RNA (SNP) | VAF 55/198 reads (28%) | called by muse, mutect2, varscan2
- LOXL1 | c.1103-965A>T | Intron (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- MATR3 | c.*501G>A | 3'UTR (SNP) | VAF 172/437 reads (39%) | called by muse, mutect2, varscan2
- MIR891A | n.1C>A | RNA (SNP) | VAF 32/109 reads (29%) | called by muse, mutect2, varscan2
- MORF4 | n.335G>C | RNA (SNP) | VAF 77/310 reads (25%) | called by muse, mutect2, varscan2
- MSC | c.534+42G>A | Intron (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- NBPF11 | c.-548-3225G>T | Intron (SNP) | VAF 50/307 reads (16%) | called by muse, mutect2, varscan2
- NUP210P1 | n.479C>A | RNA (SNP) | VAF 133/398 reads (33%) | catalogued as rs1243318004; called by muse, mutect2, varscan2
- NUPR1 | c.-29_-27del | 5'UTR (DEL) | VAF 18/46 reads (39%) | catalogued as rs776572963; called by pindel, varscan2
- OSBPL9 | c.582+17C>G | Intron (SNP) | VAF 51/234 reads (22%) | called by muse, mutect2, varscan2
- PLEKHM1P1 | n.1339A>G | RNA (SNP) | VAF 61/326 reads (19%) | called by muse, mutect2, varscan2
- RBIS | c.114+63G>A | Intron (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2, varscan2
- RFESD | c.-56G>A | 5'UTR (SNP) | VAF 15/85 reads (18%) | called by muse, varscan2
- RNF213 | c.15001-67C>G | Intron (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- SINHCAF | c.-21+844C>T | Intron (SNP) | VAF 52/329 reads (16%) | catalogued as rs1338671323; called by muse, mutect2, varscan2
- SIRPB1 | c.76+14978G>T | Intron (SNP) | VAF 130/353 reads (37%) | called by muse, mutect2, varscan2
- SLC34A2 | c.*21G>T | 3'UTR (SNP) | VAF 31/137 reads (23%) | called by muse, mutect2, varscan2
- SLC35C1 | c.-25G>T | 5'UTR (SNP) | VAF 36/195 reads (18%) | called by muse, mutect2, varscan2
- SLC35C1 | c.-24G>T | 5'UTR (SNP) | VAF 36/198 reads (18%) | called by muse, mutect2, varscan2
- SLC43A3 | c.185-30G>T | Intron (SNP) | VAF 12/64 reads (19%) | called by muse, varscan2
- SRSF7 | c.386+233G>C | Intron (SNP) | VAF 40/151 reads (26%) | called by muse, mutect2, varscan2
- SSPOP | n.9581C>T | RNA (SNP) | VAF 61/159 reads (38%) | catalogued as rs760400436, COSV65138328; called by muse, mutect2, varscan2
- SYCP2L | c.-14G>A | 5'UTR (SNP) | VAF 47/159 reads (30%) | catalogued as COSV99304431; called by muse, mutect2, varscan2
- TMA16 | chr4:163494544 C>T | 5'Flank (SNP) | VAF 35/177 reads (20%) | catalogued as rs1484546491; called by muse, mutect2, varscan2
- TMEM132E | chr17:34579274 C>G | 5'Flank (SNP) | VAF 22/54 reads (41%) | called by muse, varscan2
- TPM4 | chr19:16076046 G>C | 5'Flank (SNP) | VAF 40/114 reads (35%) | called by muse, varscan2
- TTC41P | n.254C>T | RNA (SNP) | VAF 41/268 reads (15%) | catalogued as rs1322132461; called by muse, mutect2, varscan2
- Y_RNA | chr7:75515801 T>C | 5'Flank (SNP) | VAF 50/193 reads (26%) | called by muse, mutect2, varscan2
- ZBTB7C | c.*1G>C | 3'UTR (SNP) | VAF 74/273 reads (27%) | called by muse, mutect2, varscan2
- ZNF548 | c.16-2933A>T | Intron (SNP) | VAF 60/306 reads (20%) | called by muse, mutect2, varscan2
